Somatic mutation profile of tumor specimen TCGA-G9-6339-01A (aliquot TCGA-G9-6339-01A-12D-A30X-08) from TCGA case TCGA-G9-6339, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 58.3 years (21,305 days).
Specimen TCGA-G9-6339-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 189f0d6b-938b-44af-9301-35d3144e2e4e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G9-6339-10A (Blood Derived Normal), aliquot TCGA-G9-6339-10A-01D-A30X-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/70025496-270c-4e65-b3f3-a264d617705a

The open-access MAF lists 40 somatic variants for this specimen: 35 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 4, Nonsense Mutation 2, RNA 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRB3 | c.3527C>T p.S1176L | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.196); catalogued as rs142863825, COSV53234039; called by muse, mutect2, varscan2
- ANAPC5 | c.1259T>C p.I420T | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.159); catalogued as COSV55843510; called by muse, mutect2, varscan2
- AOPEP | c.2290A>G p.S764G (on ENST00000375315 / NM_001193329.1; = p.S665G on NM_032823.5) | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.034); catalogued as rs1278631278, COSV52993161; called by muse, mutect2, varscan2
- CAT | c.529A>G p.K177E | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); catalogued as COSV53811786; called by muse, mutect2, varscan2
- CDH4 | c.926C>T p.T309M | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as rs895024295, COSV100848575, COSV64661310; called by muse, mutect2, varscan2
- FUT2 | c.203C>T p.A68V | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as rs759340211, COSV67179015; called by muse, mutect2, varscan2
- GCC2 | c.425G>T p.R142L | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV59173756, COSV59177754; called by muse, mutect2, varscan2
- GLRA1 | c.400G>A p.A134T | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.361); catalogued as COSV51017052; called by muse, mutect2, varscan2
- HCN1 | c.274G>A p.G92S | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.5); PolyPhen benign (0.153); catalogued as COSV57519894; called by muse, mutect2, varscan2
- IL1RAPL2 | c.1319G>T p.G440V | Missense Mutation (SNP) | VAF 37/77 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61165132; called by muse, mutect2, varscan2
- ILVBL | c.388G>T p.V130L | Missense Mutation (SNP) | VAF 26/138 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.597); catalogued as COSV54620664; called by muse, mutect2, varscan2
- KIF12 | c.857T>C p.L286P (on ENST00000640217; = p.L148P on NM_138424.1) | Missense Mutation (SNP) | VAF 8/129 reads (6%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.96); catalogued as COSV65117617; called by muse, mutect2
- LRIF1 | c.1162G>A p.D388N | Missense Mutation (SNP) | VAF 45/208 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as COSV63897790; called by muse, mutect2, varscan2
- NELFB | c.1242G>C p.E414D | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.92); PolyPhen benign (0.003); catalogued as COSV58025569; called by muse, mutect2, varscan2
- NOL4 | c.246C>A p.Y82* | Nonsense Mutation (SNP) | VAF 9/48 reads (19%) | catalogued as COSV52351647; called by muse, mutect2, varscan2
- NT5C1B | c.1660C>T p.R554C (on ENST00000359846 / NM_001199086.2; = p.R494C on NM_033253.4) | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs750272718, COSV58397006, COSV58399072; called by muse, mutect2, varscan2
- P2RX5 | c.383C>T p.A128V | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.43); PolyPhen benign (0.014); catalogued as rs374084034; called by muse, mutect2, varscan2
- PBXIP1 | c.121C>T p.P41S | Missense Mutation (SNP) | VAF 39/232 reads (17%) | SIFT tolerated (0.51); PolyPhen benign (0.015); catalogued as COSV63777373; called by muse, mutect2, varscan2
- PCDH15 | c.4095G>T p.K1365N | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV57267577, COSV57339717; called by muse, mutect2, varscan2
- PDPK1 | c.1225G>A p.G409S | Missense Mutation (SNP) | VAF 34/143 reads (24%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV51913517; called by muse, mutect2, varscan2
- PRAMEF12 | c.747C>G p.D249E | Missense Mutation (SNP) | VAF 21/129 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63215780; called by muse, mutect2, varscan2
- RAB4B | c.302C>T p.A101V | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.035); catalogued as rs775977385, COSV63825346; called by muse, mutect2, varscan2
- RPL37 | c.152C>G p.A51G | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.031); catalogued as COSV57038559; called by muse, varscan2
- SKIDA1 | c.1694A>T p.K565M | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV71610967; called by muse, mutect2, varscan2
- SULT1C3 | c.8A>G p.K3R | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV61253523; called by muse, mutect2, varscan2
- SZT2 | c.7417A>T p.T2473S (on ENST00000634258 / NM_001365999.1; = p.T2416S on NM_015284.4) | Missense Mutation (SNP) | VAF 42/179 reads (23%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as COSV65171248; called by muse, mutect2, varscan2
- TENM2 | c.5476G>C p.E1826Q (on ENST00000518659 / NM_001122679.2; = p.E1587Q on NM_001080428.3) | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV69134411; called by muse, mutect2
- TJAP1 | c.1309G>A p.D437N (on ENST00000372445 / NM_001146016.1; = p.D427N on NM_080604.3) | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.458); catalogued as rs142853495; called by muse, varscan2
- TOX3 | c.677G>A p.R226K | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.952); catalogued as rs1218947197, COSV54869251; called by muse, mutect2, varscan2
- TSGA10 | c.7C>T p.R3* | Nonsense Mutation (SNP) | VAF 10/61 reads (16%) | catalogued as COSV61821928; called by muse, mutect2, varscan2
- USHBP1 | c.768+1G>A p.X256_splice | Splice Site (SNP) | VAF 12/63 reads (19%) | catalogued as COSV53104583; called by muse, mutect2, varscan2
- USP3 | c.613A>G p.T205A | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as rs754979776, COSV51428286; called by muse, mutect2, varscan2
- ZFAT | c.2374A>C p.K792Q | Missense Mutation (SNP) | VAF 32/144 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV64741199; called by muse, mutect2, varscan2
- ZNF326 | c.592A>G p.T198A | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.51); PolyPhen benign (0.182); catalogued as COSV61035705; called by muse, mutect2, varscan2
- ZNF626 | c.147G>T p.K49N | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.077); catalogued as COSV52481651; called by muse, mutect2, varscan2
- ITGAX | c.918G>A p.S306= | Silent (SNP) | VAF 30/133 reads (23%) | catalogued as rs1222228671, COSV51647584; called by muse, mutect2, varscan2
- NUP133 | c.3420C>T p.F1140= | Silent (SNP) | VAF 24/95 reads (25%) | catalogued as rs774469204, COSV54571730; called by muse, mutect2, varscan2
- SYTL1 | c.312G>A p.A104= | Silent (SNP) | VAF 19/73 reads (26%) | catalogued as rs780290978, COSV58872845; called by muse, mutect2, varscan2
- ZNF101 | c.744T>C p.T248= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as rs755640847, COSV58909284; called by muse, mutect2, varscan2
- FAM183BP | n.1171C>T | RNA (SNP) | VAF 45/163 reads (28%) | catalogued as rs1379512198; called by muse, mutect2, varscan2
